Somatic mutation profile of tumor specimen 0DII44 from CCDI case PBBVKJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 1.0 years (352 days).
Specimen 0DII44: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae503fdd-f07f-487c-833c-04854a418cef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DII34 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fda3346-9319-428a-b236-7244f153615e

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 2, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK8 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 189/528 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV67420297; called by muse, mutect2, varscan2
- FIGNL1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 191/803 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV63554166; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2027G>T p.C676F | Missense Mutation (SNP) | VAF 118/413 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CNGA3 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 168/562 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- OR14K1 | c.589A>C p.S197R | Missense Mutation (SNP) | VAF 218/844 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RAP2B | c.202_210del p.R68_L70del | In Frame Del (DEL) | VAF 62/305 reads (20%) | called by mutect2, varscan2
- SEC61A2 | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 21/427 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2
- SYNE2 | c.11421G>T p.L3807F | Missense Mutation (SNP) | VAF 272/630 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TSC22D1 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 199/477 reads (42%) | called by muse, mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- ZRANB2 | c.901dup p.R301Kfs*34 (on ENST00000370920 / NM_203350.3; = p.R301Kfs*15 on NM_005455.5) | Frame Shift Ins (INS) | VAF 176/570 reads (31%) | called by mutect2, varscan2
- ADAM20 | c.193C>T p.L65= | Silent (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- ARL13B | c.507G>A p.S169= (on ENST00000394222 / NM_001174150.2; = p.S62= on NM_144996.4) | Silent (SNP) | VAF 316/785 reads (40%) | catalogued as rs199847439; called by muse, mutect2, varscan2
- GIMAP7 | c.606T>C p.S202= | Silent (SNP) | VAF 48/970 reads (5%) | catalogued as COSV57960623; called by muse, mutect2
- SERGEF | c.339G>A p.T113= | Silent (SNP) | VAF 253/587 reads (43%) | catalogued as rs779514224; called by muse, mutect2, varscan2
- AP1G2 | c.204+76del | Intron (DEL) | VAF 4/37 reads (11%) | called by mutect2, varscan2
- EIF2AK4 | c.2686+37A>G | Intron (SNP) | VAF 24/364 reads (7%) | called by muse, mutect2
